Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6YQ, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6YQ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

ICD O-3
Fibromyxosarcoma 88113
Site R Buttock NOS 49.5
QW 8/9/13

....

Clinical Diagnosis & History:
Right thigh mass clinically and radiographically liposarcoma.

Specimens Submitted:
1: Radical resection of right buttock

DIAGNOSIS:

1. Right buttock; radical resection:
- High grade myxofibrosarcoma, involving skeletal muscle and subcutis in a diffusely infiltrative growth pattern.
- Tumor size: 14.5 x 6.3 x 8.0 cm.
- The amount of gross necrosis is estimated at 20-30%.
- The surgical margins are free of tumor.
- Lymphovascular invasion is identified.
- The mitotic rate is 21 MF/10 high power fields.

NOTE: This tumor has a variegated appearance, ranging from low-grade myxoid areas to areas of more cohesive, undifferentiated epithelioid morphology. Immunohistochemical stains for CDK4 and MDM2 are negative.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh, labeled "radical resection of right buttock" and consists of a portion of skin, subcutaneous tissue and underlying muscle, overall dimensions 24 x 15 x 9cm. The skin is unremarkable (21 x 4.5cm). On cut section, there is a well-circumscribed tumor in the muscle, 14.5 x 6.3 x 8.0cm, which has a white bulging cut surface. There is 20-30% gross necrosis. Relationships to the margins are as follows: deep (black) 0.4cm (fascia); superior (blue) 4.5cm; inferior (red) 2.8cm; lateral (green) 1.0cm; medial (orange) 2.3cm; and anterior (yellow) 1.5cm.

** Continued on next page **

[page 2 of 2]
----- Page 2 of 2
Photographs are taken. Representative tissue is submitted for TPS and permanent sections.

Summary of sections:
SM - superior margin
IM - inferior margin
LM - lateral margin
MM - medial margin
DM - deep margin and tumor
S - skin
T - tumor

Summary of Sections:
Part 1: Radical resection of right buttock

Block	Sect. Site	PCs
1	am	1
1	DM	1
1	im	1
1	pm	1
1	S	1
1	SM	1
11	T	11

** End of Report **

IC/AH Discrepancy		☒
ICR Malignancy History		☒
ICR is (c, r, e):		
Reviewer initials	QUANTIFIED / DISQUALIFIED Date Reviewed: 7/23/13	

Source: NCI Genomic Data Commons file d5db7d55-ce49-4217-9c90-04a700e6a6e5 (TCGA-DX-A6YQ.7D98822E-792F-40C3-B1BF-E1877E80C118.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).